Somatic mutation profile of tumor specimen TCGA-DX-A7EL-01A (aliquot TCGA-DX-A7EL-01A-12D-A36J-09) from TCGA case TCGA-DX-A7EL, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 56.9 years (20,767 days).
Specimen TCGA-DX-A7EL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9afbd463-938c-4925-ab24-f80c78d72d3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A7EL-10A (Blood Derived Normal), aliquot TCGA-DX-A7EL-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b667a74-8fb6-4b8c-8baf-255e6cd17e64

The open-access MAF lists 41 somatic variants for this specimen: 30 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 10, Frame Shift Del 2, In Frame Del 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP10 | c.1425A>T p.L475F | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.77); catalogued as COSV100331179; called by muse, mutect2, varscan2
- CD81 | c.598G>C p.G200R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.557); catalogued as rs769059226, COSV55132116, COSV99719184; called by muse, mutect2, varscan2
- COL11A2 | c.556C>G p.H186D | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.333); catalogued as COSV100553836; called by muse, mutect2, varscan2
- CTDSPL2 | c.1239+1G>T p.X413_splice | Splice Site (SNP) | VAF 22/66 reads (33%) | catalogued as COSV99526795; called by muse, mutect2, varscan2
- CYP4F11 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs1356365095, COSV56129753; called by muse, mutect2, varscan2
- DMXL1 | c.7619G>A p.R2540Q | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.295); catalogued as rs1380673147, COSV100223813, COSV60716707; called by muse, mutect2, varscan2
- ENPP1 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.035); catalogued as COSV100719501; called by muse, mutect2, varscan2
- FANCM | c.1742G>C p.R581P | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99950944; called by muse, mutect2, varscan2
- FOXRED2 | c.1344G>C p.Q448H | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as COSV53401747; called by muse, mutect2, varscan2
- GABRA5 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.081); catalogued as COSV100165061; called by muse, mutect2
- GOLGB1 | c.6053A>T p.Q2018L | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100510709; called by muse, mutect2, varscan2
- GRIK3 | c.2731A>C p.S911R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as COSV100901865; called by muse, mutect2, varscan2
- INTS1 | c.1329G>T p.K443N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV101247844; called by muse, mutect2, varscan2
- ITPR3 | c.3701A>G p.K1234R | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.697); catalogued as COSV100967275; called by muse, mutect2, varscan2
- MORC3 | c.1697del p.S566* | Frame Shift Del (DEL) | VAF 4/41 reads (10%) | catalogued as COSV68687815; called by mutect2, pindel
- MOV10L1 | c.1490A>G p.Q497R | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as rs774685975, COSV99433594; called by muse, mutect2, varscan2
- NAGLU | c.1582A>G p.S528G | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV99864081; called by muse, mutect2, varscan2
- OR2Y1 | c.175A>T p.M59L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV100322728; called by muse, mutect2, varscan2
- PACRG | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374040289, COSV61324292; called by muse, mutect2, varscan2
- SEC24A | c.2787A>T p.Q929H | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV101295024; called by muse, mutect2, varscan2
- SOX6 | c.937G>T p.A313S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as COSV100321937; called by muse, mutect2, varscan2
- SSX1 | c.542G>T p.S181I | Missense Mutation (SNP) | VAF 76/210 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV100976378; called by muse, mutect2, varscan2
- STT3A | c.299A>C p.Y100S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV101205169; called by muse, mutect2, varscan2
- SUGCT | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100001290; called by muse, mutect2, varscan2
- TOR1A | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV100693918; called by muse, mutect2, varscan2
- TPST1 | c.68A>T p.Y23F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.468); catalogued as COSV100507037; called by muse, mutect2
- USP28 | c.413A>C p.K138T | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs771575791, COSV99135096; called by muse, mutect2, varscan2
- ZNF512 | c.296C>G p.A99G | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV100820763; called by muse, mutect2, varscan2
- ELAC2 | c.1043_1044del p.V348Afs*16 | Frame Shift Del (DEL) | VAF 28/84 reads (33%) | called by pindel, varscan2
- TACSTD2 | c.931_948del p.I311_E316del | In Frame Del (DEL) | VAF 14/82 reads (17%) | called by mutect2, pindel
- DPYSL5 | c.1446A>G p.L482= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV99982245; called by muse, mutect2, varscan2
- GATA1 | c.765T>C p.G255= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100936768; called by muse, mutect2, varscan2
- IL37 | c.639C>A p.P213= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV99636151; called by muse, mutect2, varscan2
- LZTR1 | c.165G>C p.R55= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV99301652; called by muse, mutect2, varscan2
- NPTXR | c.1017C>T p.S339= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100285439; called by muse, mutect2, varscan2
- OR10Z1 | c.624G>A p.L208= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1403437218, COSV100779000; called by muse, mutect2, varscan2
- SCN7A | c.4092G>A p.K1364= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs370436682, COSV101313155; called by muse, mutect2, varscan2
- SIDT2 | c.2316C>T p.T772= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV99637601; called by muse, mutect2
- TEKT3 | c.888G>A p.V296= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100106998; called by muse, mutect2, varscan2
- ZC3H15 | c.918T>C p.D306= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV100552044; called by muse, mutect2, varscan2
- UMODL1 | c.1899+174G>T | Intron (SNP) | VAF 4/17 reads (24%) | called by mutect2, varscan2
